Surgical pathology report (de-identified scan), TCGA case TCGA-HC-A8CY, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-A8CY-01A (Primary Tumor).

[page 1 of 4]
Patient:

Referring Physician:

DOB: Age: Gender: M

Ref#: Hosp#: Provider Group:

Date of Service: Date Received: Inpatient
Room:

Case #:
Date Reported:

FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

A. - D. PROSTATE AND LYMPH NODES, RADICAL PROSTATECTOMY AND BILATERAL ILIAC LYMPH NODE DISSECTION:

- PROSTATIC ACINAR ADENOCARCINOMA, 5+4=9.
- Bilateral involvement (left > right), largest focus 3.3 cm, ~45% of prostate.
- Extraprostatic extension: Present (multifocal on left).
- Lymphovascular and perineural invasion: Present.
- Negative for seminal vesicle invasion.
- MARGIN STATUS: POSITIVE.
- Left apex and base margins involved by carcinoma.
- ILIAC LYMPH NODES: ONE OF THREE LYMPH NODES INVOLVED (1/3).
- Left iliac node shows a micrometastasis (0.8 mm; see comment).

*ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS 061.9
4/17/14*

PATHOLOGIC TUMOR STAGING SUMMARY:

Type and grade: Prostatic acinar adenocarcinoma, 5+4=9.
Primary tumor: pT3a, with extracapsular extension (multifocal on left).
Regional lymph nodes: pN1, one of three (1/3) iliac nodes involved by tumor (left with 0.8 mm micrometastasis).
Distant metastasis: N/A.
Pathologic stage: IV.
Margin status: R1, left apex and base margins involved by carcinoma.
Lymphovascular invasion: Present.
Perineural invasion: Present.

COMMENT: Review of the frozen material shows no evidence of carcinoma. However, multiple additional blocks of the fatty portion of the left iliac lymph node were submitted for permanent section review (which not amenable to frozen section because of the fatty nature). One of these blocks shows small fragments of node (with extensive fatty-replacement) to have a micrometastasis (0.8 mm). Of note, a recent large study indicates that frozen section sensitivity for micrometastases, < 5 mm, is less than 10%: "Intraoperative frozen section assessment of pelvic lymph nodes during radical prostatectomy..."

Case #
Printed:

Page 1

This report continues... (FINAL)

MR No.

Acct No. -

[page 2 of 4]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

The previous prostate needle biopsies showing prostatic adenocarcinoma with Gleason score of up to 9 is noted.

Intradepartmental consultation with [REDACTED] is obtained. The findings are discussed [REDACTED]

Signed by

Source of Specimen:

- A. Prostatectomy
- B. Right iliac node
- C. Right iliac node
- D. Left iliac node

Clinical History/Operative Dx:

Prostate cancer

Intraoperative Diagnosis:

- B. Right iliac node, FSB1-2 - diagnosis: Negative for carcinoma.
- C. Right iliac node, FSC1-2 - diagnosis: Negative for carcinoma.
- D. Left iliac node, FSD - diagnosis: Negative for carcinoma. [REDACTED]

The intraoperative interpretation(s) was/were performed and rendered at [REDACTED]

Gross Description:

A. Single specimen designated as prostate. Initially received in the fresh state for is an 82 gram radical prostatectomy including bilateral seminal vesicles and vas deferens segments measuring 3.5 cm apex to base, 5.9 cm right to left lateral and 4.2 cm posterior-anterior. The right seminal vesicles extend 3.8 x 2.0 x 0.7 cm and the vas deferens 1.8 x 0.8 cm; the left seminal vesicles

Case #:

Printed:

Page 2

This report continues... (FINAL)

MR No. -

Acct No. -

[page 3 of 4]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

extend 4.8 x 4.8 x 0.9 cm and the vas deferens 1.2 x 0.6 cm. The radial margin of the prostate is shaggy, deep red and is now differentially inked as follows:

Right anterior-lateral: Blue,
Left anterior-lateral: Orange,
Posterior: Black.

Initial sectioning through the bilateral seminal vesicles demonstrate soft to rubbery, light pink and tan, honeycomb cut surfaces without gross tumor involvement. The bilateral seminal vesicles and vas deferens are now trimmed and the prostate is serially sectioned apex to base revealing a partially demarcated, dense, glossy, light pink and tan to focally yellow-orange tumor mass in the left body of the prostate measuring upwards of 3.3 x 3.2 x 2.2 cm. The tumor mass grossly approaches 0.2 cm of the left apex and 0.1 cm of the left base. The tumor mass grossly approaches within 0.2 cm of the nearest left radial surgical margin. Representative portions of the tumor, para-neoplastic, normal parenchyma are submitted for studies.

The remaining cut sections of the right body of prostate demonstrates multiple circumscribed, light tan nodularities near the urethral tract. The right posterior periphery of the prostate near the transition zone-origin of seminal vesicles demonstrates diffuse and well-demarcated, glossy density within 0.2 cm of the posterior surgical margin suspicious for malignancy (A13). Representative sections are submitted for microscopic evaluation in a sequential fashion apex towards base.

Cassette summary:

A1) right vas margin, seminal vesicles,
A2) left vas margin, seminal vesicles,
A3-A4) right and left apex, respectively, sectioned and submitted,
A5) right base, sectioned and submitted,
A6-A7) left base, sectioned and submitted,
A8-A10) right body of prostate, anterior-lateral, apex towards base,
A11-A14) right body of prostate, posterior-lateral, apex towards base, origin of seminal vesicles in A14,
A15-A18) left body of prostate, anterior-lateral, apex towards base,
A19-A24) left body of prostate, posterior-lateral, apex towards base, origin of seminal vesicles in A24.

B. Part B is right iliac node. Initially received in the fresh state for frozen section evaluation is a 4.0 x 3.0 x 3.0 cm portion of fatty soft tissue. Initial examination reveals a 3.0 x 2.0 x 1.5 cm rubbery fatty lymph node. The excess fat is trimmed and the lymph node tissue is submitted for frozen section evaluation with the residual frozen tissue submitted in B3 and B4 for routine histology.

C. Part C is right iliac node. Initially received in the fresh state for frozen section evaluation is a 5.0 x 4.0 x 3.0 cm yellow-tan portion of fatty soft tissue. Examination reveals a 3 x 2 x 1.5 cm fatty lymph node. The gross excess fat is trimmed and the node is submitted for frozen section evaluation with the residual frozen tissue submitted in C1 and C2 for permanent sections. Portions of attached fat containing likely lymph node parenchyma is submitted for routine histology in C3-C5.

D. Part D is left iliac node. Initially received in the fresh state for frozen section evaluation is a 8.0 x 6.0 x

Case #:

Printed:

Page 3

This report continues... (FINAL)

MR No. -

Acct No.

Patient Name

[page 4 of 4]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

3.0 cm portion of yellow-tan fat. Examination reveals a lymph node measuring up to 3.0 x 2.0 x 1.5 cm. The gross excess fat is trimmed and the obvious lymph node parenchyma is submitted for frozen section evaluation with the residual frozen tissue submitted in D1 and D2 for permanent sections. Pieces of trimmed fat with possible lymph node content is submitted in D3 and D4 for routine histology.

Microscopic Description:

A. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

B. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

C. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

D. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

Criteria	W 11/3/13	Yes	No

Case #:

Printed:

Page 4

END OF REPORT (FINAL)

Source: NCI Genomic Data Commons file d791aa38-95ee-4335-9a71-fb0dbaf941b6 (TCGA-HC-A8CY.4CF73411-E5F6-43E1-8207-076C5C0FE921.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).